Somatic mutation profile of tumor specimen MP2PRT-PAVXWB-TMP1-A (aliquot MP2PRT-PAVXWB-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVXWB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,411 days).
Specimen MP2PRT-PAVXWB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e64a445-a6f9-4ba8-b0fe-601f7bf1d983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXWB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXWB-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a68cfce-7f52-4e10-8b11-5e4156492411

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR5AC1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 131/347 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs920096059; called by muse, mutect2, varscan2
- PDE4DIP | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1553403256; called by muse, mutect2, varscan2
- ANKRD42 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BCORL1 | c.4782T>G p.D1594E | Missense Mutation (SNP) | VAF 195/689 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLVS2 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 163/385 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CSPP1 | c.2646G>A p.K882= (on ENST00000676605; = p.K841= on NM_024790.6) | Splice Region (SNP) | VAF 7/188 reads (4%) | called by muse, mutect2
- NFIB | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 114/468 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FAM47C | c.2004G>A p.P668= | Silent (SNP) | VAF 219/764 reads (29%) | catalogued as rs782772942, COSV63727168; called by muse, mutect2, varscan2
- PCDHA13 | c.2247G>A p.S749= | Silent (SNP) | VAF 144/328 reads (44%) | catalogued as rs897105384, COSV56500534; called by muse, mutect2
- PRAMEF4 | c.252C>T p.L84= | Silent (SNP) | VAF 54/442 reads (12%) | catalogued as rs761753210, COSV99340215; called by muse, mutect2, varscan2
- TMEM243 | c.234+72G>A | Intron (SNP) | VAF 23/263 reads (9%) | called by muse, mutect2
